Somatic mutation profile of tumor specimen ALCH-B5ME-TTP1-A (aliquot ALCH-B5ME-TTP1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B5ME, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,951 days).
Specimen ALCH-B5ME-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03a574b9-d878-4697-ba54-7f01282d240f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5ME-NB1-A (Blood Derived Normal), aliquot ALCH-B5ME-NB1-A-1-0-D-A85H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e658848-9a59-42fc-b2fc-9b7bb8d18f0e

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 10, RNA 2, 3'UTR 2, 5'Flank 2, Frame Shift Ins 1, Intron 1, In Frame Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs777433561; called by muse, mutect2, varscan2
- ANTXRL | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs573797659; called by muse, mutect2, varscan2
- ATP2B2 | c.1276G>A p.V426M (on ENST00000352432; = p.V392M on NM_001683.5) | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs747675057; called by muse, mutect2
- DYRK1B | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as rs1010396277; called by muse, mutect2, varscan2
- FBF1 | c.2716G>A p.E906K (on ENST00000586717; = p.E920K on NM_001319193.1) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs573986983; called by muse, mutect2, varscan2
- FMR1 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.449); catalogued as rs1414526179; called by muse, mutect2
- GYG2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs759725646; called by muse, mutect2, varscan2
- HTR5A | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as rs374005198; called by muse, mutect2, varscan2
- KCND1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782678377, COSV104373769; called by muse, mutect2, varscan2
- KLC4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1016317542; called by muse, mutect2, varscan2
- MED1 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1397723079; called by muse, mutect2, varscan2
- NAV2 | c.4801C>G p.P1601A (on ENST00000396087 / NM_001244963.2; = p.P1578A on NM_145117.5) | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.471); catalogued as rs888472613; called by muse, mutect2, varscan2
- NEPRO | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 22/368 reads (6%) | catalogued as rs1420892154; called by muse, mutect2
- OTOF | c.4963C>T p.Q1655* (on ENST00000272371 / NM_194248.3; = p.Q888* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV55518511; called by muse, mutect2
- PDZD8 | c.2977C>T p.R993W | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749964132; called by muse, mutect2
- RGL1 | c.103C>T p.Q35* (on ENST00000360851 / NM_001297672.2; = p.Q70* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/300 reads (10%) | catalogued as COSV58989640; called by muse, mutect2, varscan2
- RNF40 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 6/226 reads (3%) | catalogued as COSV100221893; called by muse, mutect2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 42/272 reads (15%) | catalogued as rs759765382; called by mutect2, varscan2
- SLCO4A1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.393); catalogued as rs145692715, COSV99415108; called by muse, mutect2, varscan2
- STC1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs766303009, COSV51687571; called by muse, mutect2
- TMEM132B | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as rs778033275, COSV54748573; called by muse, mutect2
- USP26 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs765506859; called by muse, mutect2, varscan2
- A2ML1 | c.1684-1G>T p.X562_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- ALOX5 | c.1783C>G p.R595G | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- ARHGEF18 | c.430A>G p.K144E (on ENST00000359920 / NM_001130955.2; = p.K40E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- ARHGEF9 | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDR2L | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.068); called by muse, varscan2
- CHRM3 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- CSMD3 | c.4367A>T p.Q1456L (on ENST00000297405 / NM_001363185.1; = p.Q1352L on NM_052900.3) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- DUSP8 | c.643_645del p.D215del | In Frame Del (DEL) | VAF 32/294 reads (11%) | called by mutect2, pindel
- FRMPD4 | c.2453C>G p.S818* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- HCN4 | c.1513T>A p.C505S | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECTD4 | c.5078T>G p.L1693* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MAGEE1 | c.1681T>G p.L561V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MAP3K12 | c.494T>A p.L165* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- NPY5R | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PHTF1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 34/220 reads (15%) | called by muse, mutect2, varscan2
- PPARA | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB1 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDAD1 | c.114C>A p.Y38* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SEMA4F | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SERINC2 | c.734C>A p.T245N (on ENST00000373709 / NM_178865.5; = p.T249N on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- SLC51A | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.22); called by muse, mutect2
- SLC9A7 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLCO2B1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2
- SNTG1 | c.1194C>A p.C398* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2
- TRIM66 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.7764G>C p.K2588N (on ENST00000628543; = p.K2763N on NM_152381.6) | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2
- ZNF37A | c.1610A>T p.K537I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BMP7 | c.882G>A p.T294= | Silent (SNP) | VAF 136/401 reads (34%) | catalogued as rs1391413155, COSV67782186; called by muse, mutect2, varscan2
- CAPRIN1 | c.117T>G p.S39= | Silent (SNP) | VAF 24/185 reads (13%) | called by muse, varscan2
- CYP27C1 | c.1095C>T p.H365= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as rs1382872228; called by muse, mutect2
- DDX53 | c.474A>T p.A158= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- GRIA3 | c.2655C>T p.N885= | Silent (SNP) | VAF 21/358 reads (6%) | catalogued as rs776906459; called by muse, mutect2
- GTF3C2 | c.1188G>A p.P396= | Silent (SNP) | VAF 29/216 reads (13%) | catalogued as rs150314582; called by muse, mutect2, varscan2
- IQSEC3 | c.195G>A p.P65= | Silent (SNP) | VAF 20/324 reads (6%) | catalogued as rs1555065631; called by muse, mutect2
- MYO7B | c.1470C>T p.T490= | Silent (SNP) | VAF 41/273 reads (15%) | catalogued as rs774301947, COSV101268131, COSV67345495; called by muse, mutect2, varscan2
- PCDHGB7 | c.192C>T p.R64= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as COSV53900968; called by muse, mutect2, varscan2
- VNN1 | c.321C>T p.I107= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- ZNF827 | c.555A>G p.P185= | Silent (SNP) | VAF 44/256 reads (17%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504016 T>A | 5'Flank (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505731 del TTG | 5'Flank (DEL) | VAF 22/174 reads (13%) | catalogued as rs767159143; called by mutect2, pindel, varscan2
- B9D1 | c.-102A>C | 5'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- C1orf229 | n.449A>G | RNA (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1373G>A | RNA (SNP) | VAF 14/214 reads (7%) | catalogued as rs767220377, COSV52835244; called by muse, mutect2
- SLC44A1 | c.*863G>A | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- WNK2 | c.6739+49del | Intron (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- ZNF276 | c.*749C>G | 3'UTR (SNP) | VAF 47/252 reads (19%) | catalogued as rs1010028646; called by muse, mutect2, varscan2
